Somatic mutation profile of tumor specimen TARGET-30-PAMCXF-01A (aliquot TARGET-30-PAMCXF-01A-01W) from TARGET case TARGET-30-PAMCXF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.1 years (765 days).
Specimen TARGET-30-PAMCXF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f7d7ef4-aaac-4f28-9e4c-dddca3b9b460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMCXF-10A (Blood Derived Normal), aliquot TARGET-30-PAMCXF-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e592f6e4-a123-4976-9874-99b6314fd88f

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT1 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52868421; called by muse, mutect2
- MAEL | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV63305860; called by mutect2, varscan2
- SH2B1 | c.1760G>T p.C587F | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59465508; called by muse, mutect2, varscan2
- TIGD6 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); called by muse, mutect2
- NAALADL1 | c.378C>A p.I126= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
